HCMI case HCM-BROD-0954-C34 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ee582bc-c8f2-4c31-836a-e9e3fd8ecd72

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.3 years (24,222 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IB; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G3; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 8 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 537 days (1.5 years); Disease response: Complete Response; Progression or recurrence: No.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- EGFR: Negative.
- ROS1 rearrangement (FISH): Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 163 cm; BMI: 28.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 25; Tobacco smoking quit year: 2019.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0954-C34-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0954-C34-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 18; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 4.
  Slide HCM-BROD-0954-C34-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 1; Percent stromal cells: 17; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 4.
- Sample HCM-BROD-0954-C34-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0954-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
